Somatic mutation profile of tumor specimen TCGA-P5-A5EZ-01A (aliquot TCGA-P5-A5EZ-01A-11D-A27K-08) from TCGA case TCGA-P5-A5EZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 39.4 years (14,375 days).
Specimen TCGA-P5-A5EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce971d18-fb71-4226-a024-575be007c38a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5EZ-10A (Blood Derived Normal), aliquot TCGA-P5-A5EZ-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85cef403-d593-46d7-91a0-567b93b859f5

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC1A4 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761533681, CM157291, COSV52235153; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 41/84 reads (49%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APOB | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs149357946, COSV51953773; ClinVar: likely benign; called by muse, mutect2, varscan2
- AUTS2 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.4); catalogued as COSV61431587; called by muse, mutect2
- CNTN2 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764275222, COSV59352121; called by muse, mutect2, varscan2
- CXCR2 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 102/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201103729, COSV59280934; called by muse, mutect2, varscan2
- DCAF8 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV58786067; called by muse, mutect2, varscan2
- DNAH11 | c.3359T>C p.L1120S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60982958; called by muse, mutect2, varscan2
- ELAVL2 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 11/154 reads (7%) | catalogued as COSV56365323; called by muse, mutect2
- ESRP1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198582850, COSV64409616; called by muse, mutect2
- GUCA1A | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 39/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50005432; called by muse, mutect2
- HIRA | c.1560G>C p.E520D | Missense Mutation (SNP) | VAF 86/245 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV54280110; called by muse, mutect2, varscan2
- KNDC1 | c.3884A>G p.D1295G | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100466370; called by muse, mutect2
- KRT37 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1229877545, COSV56660140; called by muse, mutect2, varscan2
- OR9G1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100380585; called by muse, mutect2
- OTOF | c.4579C>T p.R1527C (on ENST00000272371 / NM_194248.3; = p.R760C on NM_004802.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs775508390, COSV55520894; called by muse, mutect2, varscan2
- PDZD2 | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV56873226; called by muse, mutect2
- PRMT5 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV53548448; called by muse, mutect2, varscan2
- ROS1 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100877735; called by muse, mutect2
- SENP2 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV56198137; called by muse, mutect2, varscan2
- SERPINA3 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as COSV67587217; called by muse, mutect2, varscan2
- SLC35F5 | c.1316T>C p.I439T | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs755102738, COSV55520848; called by muse, varscan2
- TEP1 | c.2824C>T p.R942C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745737029, COSV53000680; called by muse, mutect2, varscan2
- TP63 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM001823, CM030108, COSV53215406, COSV53221840; called by muse, mutect2
- TTC12 | c.863T>A p.F288Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV59100262; called by muse, mutect2
- TTC17 | c.3311C>T p.A1104V | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50021370; called by muse, mutect2, varscan2
- BOD1L1 | c.5778A>C p.A1926= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs781399497, COSV50071173; called by muse, mutect2, varscan2
- CCR7 | c.927C>T p.D309= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs747194288, COSV55850870; called by muse, mutect2
- HCK | c.153C>T p.Y51= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs112610391, COSV52942689; called by muse, mutect2, varscan2
- IRS1 | c.3222G>A p.R1074= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV59340237; called by muse, mutect2, varscan2
- KLF3 | c.195G>A p.T65= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs373502495; called by muse, mutect2, varscan2
- LIMK2 | c.1110G>A p.Q370= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV59184754; called by muse, mutect2
- MUC16 | c.12396A>T p.S4132= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as COSV67495821; called by muse, mutect2
- NCAPD2 | c.2589C>G p.L863= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV59702827; called by muse, mutect2
- PCDHGA7 | c.309G>A p.L103= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV54038672; called by muse, mutect2
- PLCD4 | c.2052G>C p.G684= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as COSV68743743, COSV68745887; called by muse, mutect2, varscan2
- ZDHHC14 | c.828C>T p.I276= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs779328730, COSV58196911; called by muse, mutect2, varscan2
- HERC2P3 | n.616C>A | RNA (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
